Somatic mutation profile of tumor specimen MMRF_2225_1_BM_CD138pos (aliquot MMRF_2225_1_BM_CD138pos_T1_KHS5U_L11021) from MMRF case MMRF_2225, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.3 years (19,472 days).
Specimen MMRF_2225_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec9bd810-ac54-4f9e-a963-ae8eee6a0320.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2225_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2225_1_PB_WBC_C2_KHS5U_L11022; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e086674-553c-4a26-8e37-bc1ff66d7a6e

The open-access MAF lists 140 somatic variants for this specimen: 59 protein-altering or splice-affecting, 15 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 41, Silent 15, Intron 13, 5'UTR 8, Nonsense Mutation 5, 3'Flank 2, Splice Site 2, 5'Flank 2, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 20/120 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CA12 | c.316A>T p.I106F | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV99458675; called by muse, mutect2, varscan2
- COL18A1 | c.4186G>A p.E1396K (on ENST00000359759 / NM_130444.3; = p.E1161K on NM_030582.4) | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs774337224, COSV100645247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL23A1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs779240932; called by muse, mutect2, varscan2
- ERRFI1 | c.1322C>G p.S441* | Nonsense Mutation (SNP) | VAF 89/512 reads (17%) | catalogued as COSV101088358, COSV66311366; called by muse, mutect2, varscan2
- FAM160A1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1195689531; called by muse, mutect2, varscan2
- FTO | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as rs531215275, COSV67113014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FZD8 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs1376058430, COSV65967648, COSV65968519; called by muse, mutect2, varscan2
- HHIPL2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs753340048, COSV58567177; called by muse, mutect2, varscan2
- LCOR | c.3547G>A p.V1183I | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as rs1193321455; called by muse, mutect2
- MEFV | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 86/480 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as rs104895202; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- MGAT5B | c.2104G>A p.D702N (on ENST00000569840 / NM_001199172.2; = p.D700N on NM_144677.3) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as rs201168609; called by muse, mutect2, varscan2
- NECTIN1 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755800836, COSV50603252; called by muse, mutect2, varscan2
- NHS | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756326507; called by muse, mutect2, varscan2
- PTCD3 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs1352530481, COSV54480741; called by muse, mutect2, varscan2
- SLC6A16 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs1321475223; called by muse, mutect2, varscan2
- TBX21 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.422); catalogued as rs1246296638; called by muse, mutect2
- TCL1A | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as COSV68085134; called by muse, mutect2, varscan2
- XBP1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752517775, COSV53273888, COSV99321699; called by muse, mutect2, varscan2
- ZAR1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756437431, COSV99906914; called by muse, mutect2, varscan2
- ZNF318 | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as rs1372457477; called by muse, mutect2, varscan2
- ZNF532 | c.2062G>C p.D688H | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV60174058; called by muse, mutect2
- ZNF536 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138241491; called by muse, mutect2, varscan2
- ACO1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 42/260 reads (16%) | called by muse, mutect2, varscan2
- AFAP1 | c.1994G>T p.S665I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ANLN | c.2148C>G p.I716M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- BCOR | c.4114G>C p.E1372Q (on ENST00000378444 / NM_001123385.2; = p.E1338Q on NM_017745.6) | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2
- BRSK2 | c.55T>C p.Y19H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CRISP3 | c.71C>A p.S24Y (on ENST00000371159 / NM_001368123.1; = p.S16Y on NM_001190986.2) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- DYNC1H1 | c.10413A>G p.K3471= | Splice Region (SNP) | VAF 10/66 reads (15%) | called by mutect2, varscan2
- FAM110A | c.632_637del p.L211_D212del | In Frame Del (DEL) | VAF 20/166 reads (12%) | called by mutect2, pindel
- FMR1 | c.660T>A p.H220Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- IGLV3-27 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- JADE1 | c.13C>A p.R5S | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- MAP3K4 | c.3427+1G>T p.X1143_splice | Splice Site (SNP) | VAF 42/319 reads (13%) | called by muse, mutect2, varscan2
- MED12 | c.5059C>A p.P1687T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- MPP1 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTERF1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- MYO9A | c.3986_3987insTT p.S1330* | Frame Shift Ins (INS) | VAF 32/145 reads (22%) | called by mutect2, pindel, varscan2
- NUP210L | c.3124G>A p.D1042N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- OR52N2 | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 70/477 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ORC2 | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL1A | c.2611G>A p.D871N (on ENST00000319481 / NM_080597.4; = p.D358N on NM_018030.4) | Missense Mutation (SNP) | VAF 95/327 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD6A | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PCDHA7 | c.2213C>G p.T738S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, varscan2
- PCLO | c.13529-2A>G p.X4510_splice | Splice Site (SNP) | VAF 35/173 reads (20%) | called by muse, mutect2, varscan2
- PRRC2C | c.7636C>T p.L2546F (on ENST00000367742; = p.L2544F on NM_015172.4) | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBM47 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRAGA | c.434A>G p.E145G | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- RTTN | c.4330G>A p.V1444I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEC31A | c.3398C>T p.S1133L (on ENST00000355196 / NM_001318120.1; = p.S1094L on NM_016211.4) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TEX55 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 70/420 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TIFA | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 31/188 reads (16%) | called by muse, mutect2, varscan2
- TRIM16L | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- URB1 | c.5152G>A p.G1718R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZCCHC4 | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFR | c.1660C>T p.L554F | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF45 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- ZNF462 | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- C9orf131 | c.588C>T p.F196= | Silent (SNP) | VAF 25/162 reads (15%) | called by muse, mutect2, varscan2
- CDA | c.63C>T p.C21= | Silent (SNP) | VAF 59/224 reads (26%) | catalogued as rs777544429; called by muse, mutect2, varscan2
- CFAP77 | c.450C>T p.H150= | Silent (SNP) | VAF 49/274 reads (18%) | catalogued as rs759081377, COSV58014883; called by muse, mutect2, varscan2
- COL6A3 | c.576G>A p.P192= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs141560881, COSV55101818; ClinVar: likely benign; called by muse, mutect2, varscan2
- HIVEP2 | c.1878G>A p.K626= | Silent (SNP) | VAF 39/261 reads (15%) | called by muse, mutect2, varscan2
- KPNA2 | c.1011C>T p.L337= | Silent (SNP) | VAF 40/341 reads (12%) | catalogued as rs374767668; called by muse, mutect2, varscan2
- MAGI1 | c.3798G>A p.P1266= | Silent (SNP) | VAF 69/445 reads (16%) | catalogued as rs1329036742; called by muse, mutect2, varscan2
- MUC5AC | c.177C>G p.V59= | Silent (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- MYBPC3 | c.3824G>A p.*1275= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1378278382; called by muse, mutect2, varscan2
- MYOC | c.324C>T p.A108= | Silent (SNP) | VAF 34/186 reads (18%) | called by muse, mutect2, varscan2
- PCDHA7 | c.2128C>T p.L710= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, varscan2
- PTPRO | c.144C>T p.D48= | Silent (SNP) | VAF 21/182 reads (12%) | catalogued as rs755731862, COSV55506898, COSV99840497; called by muse, mutect2, varscan2
- RNF19A | c.603C>T p.Y201= | Silent (SNP) | VAF 60/325 reads (18%) | catalogued as rs568403328, COSV61993448; called by muse, mutect2, varscan2
- ROR1 | c.972C>A p.T324= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- SLC16A11 | c.600C>T p.L200= (on ENST00000308009; = p.L176= on NM_153357.3) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs1477537261; called by muse, mutect2, varscan2
- ABCC12 | c.-24C>T | 5'UTR (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- ADD1 | c.*906G>A | 3'UTR (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- ATOX1 | c.7-231A>G | Intron (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.*1237A>G | 3'UTR (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- BCDIN3D | c.234+11G>T | Intron (SNP) | VAF 90/584 reads (15%) | called by muse, mutect2, varscan2
- BTBD7 | c.*4426T>G | 3'UTR (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- CBY1 | c.*522C>G | 3'UTR (SNP) | VAF 9/75 reads (12%) | called by muse, varscan2
- CDH16 | c.*145C>T | 3'UTR (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- CEP57 | c.*1317G>A | 3'UTR (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- CLNK | c.*2168T>C | 3'UTR (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- COL18A1 | c.3678+53G>A | Intron (SNP) | VAF 18/62 reads (29%) | catalogued as rs1482645240; called by muse, mutect2, varscan2
- COX7A2 | c.-39G>A | 5'UTR (SNP) | VAF 58/344 reads (17%) | called by muse, mutect2, varscan2
- DPY19L1 | c.*2271A>C | 3'UTR (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- DTX1 | c.-145C>A | 5'UTR (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- EIF4E | c.*5403C>G | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2
- FAM234B | c.*854G>C | 3'UTR (SNP) | VAF 14/95 reads (15%) | catalogued as rs575072593; called by muse, mutect2, varscan2
- FAT3 | c.*3506T>A | 3'UTR (SNP) | VAF 7/46 reads (15%) | catalogued as rs1278512040; called by muse, mutect2, varscan2
- GABRG1 | c.*4424A>G | 3'UTR (SNP) | VAF 40/241 reads (17%) | catalogued as rs1465149994; called by muse, mutect2, varscan2
- GABRR1 | c.*616C>T | 3'UTR (SNP) | VAF 7/63 reads (11%) | catalogued as rs745668280; called by muse, mutect2, varscan2
- GCC2 | c.*1159C>G | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- GRIA1 | c.*1894G>A | 3'UTR (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- IL1RL1 | c.970+489T>A | Intron (SNP) | VAF 12/56 reads (21%) | called by muse, varscan2
- KCNT2 | c.-116T>C | 5'UTR (SNP) | VAF 14/64 reads (22%) | catalogued as rs1281498657; called by muse, mutect2, varscan2
- KLHL7 | c.442+777T>G | Intron (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- LHCGR | c.*674C>A | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- MAGI2 | c.*379G>A | 3'UTR (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- MAP1LC3B | chr16:87392106 G>A | 5'Flank (SNP) | VAF 14/71 reads (20%) | catalogued as rs1046875577; called by muse, mutect2, varscan2
- MAP2 | c.455-1966G>A | Intron (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- MEPE | c.-1G>C | 5'UTR (SNP) | VAF 68/504 reads (13%) | catalogued as COSV100734966; called by muse, mutect2, varscan2
- MID1IP1 | c.-148C>T | 5'UTR (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- MRPS16 | c.*1708G>A | 3'UTR (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- MYO1E | c.-119T>C | 5'UTR (SNP) | VAF 17/135 reads (13%) | called by muse, mutect2, varscan2
- NRXN1 | c.*51G>C | 3'UTR (SNP) | VAF 12/52 reads (23%) | catalogued as rs1459814717; called by muse, mutect2, varscan2
- PARD3B | c.*2350G>A | 3'UTR (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- PGLYRP2 | c.-3A>G | 5'UTR (SNP) | VAF 45/246 reads (18%) | called by muse, mutect2, varscan2
- PHF6 | c.*1133A>C | 3'UTR (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- PLOD1 | c.*214G>A | 3'UTR (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- PZP | c.428-44C>T | Intron (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2, varscan2
- RAB35 | c.*1481T>G | 3'UTR (SNP) | VAF 36/189 reads (19%) | called by muse, mutect2, varscan2
- RAET1E | chr6:149884320 T>G | 3'Flank (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- RASSF2 | c.*1641G>T | 3'UTR (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- RCBTB1 | c.*2013C>T | 3'UTR (SNP) | VAF 15/92 reads (16%) | catalogued as rs993681074; called by muse, varscan2
- RCBTB1 | c.*1944C>G | 3'UTR (SNP) | VAF 23/115 reads (20%) | called by muse, varscan2
- RPS6KA3 | c.*3180T>C | 3'UTR (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2, varscan2
- RRP12 | chr10:97401386 A>G | 5'Flank (SNP) | VAF 20/239 reads (8%) | called by muse, mutect2
- RWDD1 | c.*104C>T | 3'UTR (SNP) | VAF 18/117 reads (15%) | catalogued as rs1325991858; called by muse, mutect2, varscan2
- SDC1 | c.66+1523G>A | Intron (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- SEC24B | c.*136G>C | 3'UTR (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- SLC17A8 | c.*854A>G | 3'UTR (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*9417G>C | 3'UTR (SNP) | VAF 19/94 reads (20%) | catalogued as rs986130060; called by muse, mutect2, varscan2
- SLC35D1 | c.*3650G>A | 3'UTR (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- STAT1 | c.*1512C>T | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- TK2 | c.31+42T>C | Intron (SNP) | VAF 56/389 reads (14%) | called by muse, mutect2, varscan2
- TMEM164 | c.*1478G>T | 3'UTR (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- TMEM175 | c.842+508G>C | Intron (SNP) | VAF 25/260 reads (10%) | catalogued as rs1243709090; called by muse, mutect2, varscan2
- TMEM45A | c.*8G>A | 3'UTR (SNP) | VAF 43/266 reads (16%) | called by muse, mutect2, varscan2
- TRIM9 | c.1603+158G>C | Intron (SNP) | VAF 9/67 reads (13%) | catalogued as rs1356194766; called by muse, mutect2, varscan2
- UBE2A | c.*258T>A | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- UBE2W | c.*400C>T | 3'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- UBXN4 | c.*960A>G | 3'UTR (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- UQCRC2 | c.1124+94G>A | Intron (SNP) | VAF 4/37 reads (11%) | catalogued as rs1478946703; called by muse, mutect2
- VARS1 | c.-34+148C>T | Intron (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- VASH1 | c.*3410G>A | 3'UTR (SNP) | VAF 28/270 reads (10%) | called by muse, mutect2
- VGLL3 | c.*2938G>C | 3'UTR (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- WWC3 | c.*1256G>C | 3'UTR (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- ZBTB38 | chr3:141449222 G>A | 3'Flank (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2
